Gene-level copy-number profile of specimen HCM-SANG-0284-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-0284-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0284-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e250f713-93d2-47c8-acdf-7ec6fcf2c89e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0284-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/2f8d6f96-e3e9-4f8d-b8f6-f354aca33a45

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 78; copy number 2: 14,857; copy number 3: 28,301; copy number 4: 12,795; copy number 5: 205; copy number 6: 866; copy number 7: 10; copy number 8: 1,292.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,302 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:10,449,820–10,779,944, 1 gene, copy number 7 (within-gene range 4–7): MGC4859.
- chr7:10,702,676–11,520,175, 8 genes, copy number 7 (within-gene range 5–7): AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11.
- chr7:11,406,955–11,414,078, 1 gene, copy number 7 (within-gene range 5–7): AC004160.2.
- chr13:19,345,049–114,337,626, 1,292 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 78. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
